CCDI case PBBLBN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4f8fe048-20b1-4092-bc08-a2b8ea3ba98a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.3 years (839 days).

Biospecimens (4 samples)
- Sample 0DBFC8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DBFCD, 0DBHZB (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBFCH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
